Gene-level copy-number profile of tumor specimen TCGA-UC-A7PG-01A from TCGA case TCGA-UC-A7PG, project TCGA-CESC (Cervical Squamous Cell Carcinoma and Endocervical Adenocarcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Cervix uteri; FIGO stage: Stage IIIB; Tumor grade: G1; Age at diagnosis: 44.4 years (16,231 days).
Specimen TCGA-UC-A7PG-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-CESC.c6364b2e-7fb9-4c8e-b819-b28934b68a81.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-UC-A7PG-11C (solid tissue normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 808 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/4b9d6dd5-ca2d-4d35-9ae6-741b1687b8a6

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 1: 1,677; copy number 2: 24,804; copy number 3: 25,918; copy number 4: 4,320; copy number 5: 437; copy number 6: 2,659.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-UC-A7PG-01A-11D-A42N-01): tumor purity 0.55, ploidy 2.65, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 3,096 genes in 6 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:119,558,755–248,919,946, 2,659 genes, copy number 6 (broad region; genes not listed).
- chr3:98,390,666–102,755,170, 80 genes, copy number 5 (broad region; genes not listed).
- chr3:144,442,211–158,732,489, 239 genes, copy number 5 (broad region; genes not listed).
- chr3:158,732,263–158,784,070, 2 genes, copy number 5 (within-gene range 3–5): AC080013.1, RPL35AP9.
- chr20:5,426,892–13,996,443, 113 genes, copy number 5 (within-gene range 4–5) (broad region; genes not listed).
- chr20:14,003,508–14,223,325, 3 genes, copy number 5: RPS3P1, AIMP1P1, RN7SL864P.

Autosomal genes at a single copy (total copy number 1): 1,677. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
